TCGA case TCGA-RR-A6KC — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: St. Joseph's Hospital AZ. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/50d1d4af-7d62-4c48-88c1-890bb2370353

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Dead; Days to death: 625 days (1.7 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.2; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 55.6 years (20,302 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 56.6 years (20,671 days); Days to diagnosis: 369 days (1.0 years); Prior treatment: Yes.

Follow-up (2 entries)
- Day 369 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 369 days (1.0 years).
- Follow-up contact recording only the day: day 625.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-RR-A6KC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 180 mg.
  Slide TCGA-RR-A6KC-01A-03-TSC: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-RR-A6KC-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-RR-A6KC-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Glioblastoma Multiforme (GBM); History lgg diagnosis of brain tissue: No; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 625 days; disease-specific survival: event status not recorded, 625 days; disease-free interval: event (new tumor event after initially disease-free), 369 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 369 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-RR-A6KC-01A-31D-A33S-01): tumor purity 0.77, ploidy 2.03, whole-genome doublings 0.
